Gene-level copy-number profile of tumor specimen ALCH-AE13-TTP1-A from ALCHEMIST case ALCH-AE13, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 61.5 years (22,465 days).
Specimen ALCH-AE13-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d1b21c05-8f7c-43ef-b200-eb835970f656.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE13-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/e76988ac-518d-4871-ad55-ae0c3e1f6dfd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 149; copy number 1: 8,453; copy number 2: 42,329; copy number 3: 5,413; copy number 4: 1,881; copy number 5: 34; copy number 7: 58; copy number 9: 2; copy number 11: 28; copy number 14: 27; copy number 21: 21.

Homozygous deletions (total copy number 0; autosomes only): 133 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,693,124–7,694,844, 1 gene (within-gene range 0–2): AL359881.3.
- chr2:231,645,998–231,646,273, 1 gene: RN7SL499P.
- chr2:232,343,116–232,351,309, 2 genes (within-gene range 0–2): NRBF2P6, ECEL1P3.
- chr2:232,442,034–232,447,418, 1 gene: DIS3L2P1.
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr7:128,081,861–128,081,960, 1 gene (within-gene range 0–2): MIR593.
- chr9:123,485,529–123,485,622, 1 gene (within-gene range 0–1): MIR7150.
- chr11:70,467,856–71,524,107, 16 genes (within-gene range 0–21): SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1, ACTE1P, DHCR7, AP002387.1, NADSYN1, MIR6754, AP000867.2.
- chr11:72,576,141–72,814,054, 14 genes (within-gene range 0–2): PDE2A, PDE2A-AS2, MIR139, RNU7-105P, PDE2A-AS1, ARAP1, ARAP1-AS1, AP003065.1, ARAP1-AS2, RPS12P20, STARD10, Y_RNA, MIR4692, AP002381.2.
- chr11:76,186,325–76,216,025, 3 genes: WNT11, AP000785.1, LINC02761.
- chr11:77,066,961–77,215,241, 3 genes: CAPN5, OMP, MYO7A.
- chr13:114,107,569–114,108,820, 1 gene (within-gene range 0–2): RASA3-IT1.
- chr15:25,176,832–25,257,027, 42 genes (within-gene range 0–2): SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr15:64,739,891–64,825,668, 3 genes: RBPMS2, MIR1272, PIF1.
- chr15:90,839,641–90,853,608, 1 gene: AC124248.1.
- chr15:90,954,870–90,963,125, 1 gene (within-gene range 0–1): RCCD1.
- chr16:83,899,115–83,966,332, 3 genes (within-gene range 0–2): MLYCD, AC009119.2, OSGIN1.
- chr17:2,748,078–2,748,182, 2 genes (within-gene range 0–1): MIR1253, hsa-mir-1253.
- chr17:16,414,524–16,416,689, 1 gene (within-gene range 0–1): AC093484.2.
- chr17:19,020,656–19,047,011, 2 genes (within-gene range 0–1): GRAP, AC003957.1.
- chr17:19,112,000–19,214,045, 14 genes: AC007952.4, SNORD3D, SNORD3D, GRAPL, AC007952.6, AC007952.9, AC007952.1, AC007952.5, AC007952.8, KYNUP1, SNORD3A, SNORD3C, AC106017.1, KYNUP3.
- chr17:19,219,143–19,222,527, 1 gene (within-gene range 0–1): AC106017.2.
- chr18:37,243,040–37,762,131, 6 genes (within-gene range 0–2): CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr19:19,645,198–19,663,676, 1 gene: ATP13A1.
- chr20:3,227,417–3,239,559, 1 gene: SLC4A11.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 169 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:73,397,114–74,589,481, 31 genes, copy number 5: ALB, AFP, AFM, LINC02499, AC074250.1, RASSF6, UMLILO, CXCL8, AC112518.1, CXCL6, PPBPP1, PF4V1, CXCL1, HNRNPA1P55, CXCL1P1, PF4, PPBP, CXCL5, AC097709.1, RN7SL218P, CXCL3, PPBPP2, AC093677.1, CXCL2, MTHFD2L, AC093677.2, EPGN, EREG, AC021180.1, AREG, AC239584.1.
- chr11:68,903,863–70,436,584, 48 genes, copy number 14–21: IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr14:103,928,456–104,052,667, 3 genes, copy number 5 (within-gene range 2–5): TDRD9, RD3L, RN7SL634P.
- chr18:508,568–4,459,458, 87 genes, copy number 7–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,076. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
